Somatic mutation profile of tumor specimen 0DU07R from CCDI case PBCJYN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 10.3 years (3,774 days).
Specimen 0DU07R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ecd4a66-b3a5-4263-8b3a-e04bc9d1ea51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU07M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df81fbff-a0d8-4f4e-b8d4-fed16708f57c

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FYB1 | c.1199C>T p.P400L | Missense Mutation (SNP) | VAF 364/1333 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs746531540, COSV60941976; called by muse, mutect2, varscan2
- PRTFDC1 | c.187G>C p.D63H | Missense Mutation (SNP) | VAF 202/1174 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as rs768261934, COSV100196756; called by muse, mutect2
- ANKRD26 | c.242+1G>T p.X81_splice | Splice Site (SNP) | VAF 125/835 reads (15%) | called by muse, varscan2
- ANKRD26 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 130/925 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.055); called by muse, varscan2
- ANKRD26 | c.5A>T p.K2M | Missense Mutation (SNP) | VAF 185/1114 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CCT8L2 | c.*87G>C | 3'UTR (SNP) | VAF 30/132 reads (23%) | called by muse, mutect2, varscan2
